Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAHY, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAHY-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Left orchidectomy; seminoma; diameter 3 cm; no invasion of rete testis; no angio-invasion; no invasion of tunica albuginea; epididymis free of tumor; surgical margin of spermatic cord free of tumor.

Date of procurement (= date of orchidectomy):

ICD O-3
Seminoma NOS 9061/3
Site: Testis NOS C62.9
AJ 3/2/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 7751aca9-9272-4354-8531-76d729f3b877 (TCGA-2G-AAHY-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).